Somatic mutation profile of tumor specimen MP2PRT-PAVFYW-TBP1-A (aliquot MP2PRT-PAVFYW-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVFYW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,291 days).
Specimen MP2PRT-PAVFYW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75e6026c-8810-47d5-aa1c-90180ff3b4e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFYW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFYW-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74c13c9d-2fdd-4bca-b02f-f6c23f1d2f71

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.2134C>T p.R712* (on ENST00000303395 / NM_001202435.3; = p.R701* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/350 reads (6%) | catalogued as rs794726730, CM024300, CX096176, COSV57668399; ClinVar: pathogenic; called by muse, mutect2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 143/385 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- IGHV2-26 | chr14:106301392 GTGGT>TC | Missense Mutation (DEL) | VAF 12/74 reads (16%) | called by pindel, varscan2*
- SPEN | c.5806C>T p.R1936* | Nonsense Mutation (SNP) | VAF 199/526 reads (38%) | called by muse, mutect2, varscan2
- SVEP1 | c.7582T>A p.F2528I | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- VEGFC | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 83/266 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNGA4 | c.708G>A p.P236= | Silent (SNP) | VAF 36/492 reads (7%) | catalogued as rs1228514054, COSV101171917; called by muse, mutect2
- MED12 | c.5253G>A p.P1751= | Silent (SNP) | VAF 260/702 reads (37%) | catalogued as rs770067057; ClinVar: likely benign; called by muse, mutect2, varscan2
- SESN2 | c.1386G>A p.A462= | Silent (SNP) | VAF 155/414 reads (37%) | catalogued as rs763448717, COSV99455549; called by muse, mutect2, varscan2
- SHFL | c.690G>A p.K230= | Silent (SNP) | VAF 24/579 reads (4%) | called by muse, mutect2
- SH3D19 | c.-578C>T | 5'UTR (SNP) | VAF 149/434 reads (34%) | catalogued as rs1001272633; called by muse, mutect2, varscan2
